Somatic mutation profile of tumor specimen 0DMUZ8 from CCDI case PBCAUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.2 years (5,902 days).
Specimen 0DMUZ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8e1bb96-e0e6-46c6-a446-6f7948ae8aa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUXE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ad82da-1791-4780-a202-a21eb1a54099

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12652C>T p.R4218C | Missense Mutation (SNP) | VAF 156/740 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs902514434; called by muse, mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 14/415 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by muse, mutect2
- ATP2B3 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 108/576 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs782752200; called by muse, mutect2, varscan2
- RBP3 | c.1426A>G p.M476V | Missense Mutation (SNP) | VAF 114/596 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1448042207; called by muse, mutect2, varscan2
- TTC25 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 144/800 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs181295455; called by muse, mutect2, varscan2
- CDC14B | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- CYP11A1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 25/862 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2
- HEATR5B | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 18/579 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.39); called by muse, mutect2
- MUC5B | c.7277C>A p.P2426H | Missense Mutation (SNP) | VAF 146/708 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GK2 | c.33G>A p.P11= | Silent (SNP) | VAF 90/535 reads (17%) | catalogued as rs762640754; called by muse, mutect2, varscan2
- KRT73 | c.957C>T p.A319= | Silent (SNP) | VAF 100/716 reads (14%) | catalogued as rs545735975, COSV59841293; called by muse, mutect2, varscan2
- RYR3 | c.11143+87G>A | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs905469434; called by muse, mutect2
- TRAM1L1 | c.-46G>A | 5'UTR (SNP) | VAF 63/283 reads (22%) | called by muse, mutect2, varscan2
